TCGA case TCGA-FR-A2OS — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f1a69042-8347-45c1-b925-8526a8443b86

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 368 days (1.0 years).

Diagnoses (6)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.7; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 49.6 years (18,122 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 368 days (1.0 years); Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 311 days; Days to treatment end: 368 days (1.0 years); Number of cycles: 1; Prescribed dose: 400; Prescribed dose units: mg/day; Route of administration: Oral.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: V; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Recorded as not given: Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Skin of scalp and neck. Age at diagnosis: 50.4 years (18,405 days); Days to diagnosis: 283 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for progressive disease; Surgery, NOS, for recurrent disease.
4. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 50.4 years (18,405 days); Days to diagnosis: 283 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Abdomen, NOS. Age at diagnosis: 50.4 years (18,405 days); Days to diagnosis: 283 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 50.5 years (18,438 days); Days to diagnosis: 316 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 283 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 283 days.
- Day 283 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 283 days.
- Day 283 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of scalp and neck; Days to progression: 283 days.
- Day 283 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 283 days.
- Day 316 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 316 days.
- Days to follow up: 368 days (1.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase: Elevated.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 164 cm; BMI: 31.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FR-A2OS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-FR-A2OS-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FR-A2OS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FR-A2OS-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 368 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 368 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 283 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FR-A2OS-01A-11D-A219-01): tumor purity 0.65, ploidy 4.07, whole-genome doublings 1.
